CPTAC case C3L-02041 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9352d2fd-ae75-4b27-95f5-96f66fda7958

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1965; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Temporal lobe; Age at diagnosis: 51.8 years (18,904 days); Year of diagnosis: 2017; Days to last known disease status: 1,030 days (2.8 years); Progression or recurrence: yes; Days to recurrence: 235 days; Days to last follow up: 1,030 days (2.8 years).
   Pathology details: Greatest tumor dimension: 0 cm.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (3 entries)
- Days to follow up: 668 days (1.8 years); Karnofsky performance status: 60.
- Days to follow up: 1,030 days (2.8 years); Progression or recurrence: Yes; Days to recurrence: 235 days; Karnofsky performance status: 60.
- Follow-up contact recording only the day: day 392.

Other clinical attributes
- Weight: 56.36 kg; Height: 170.18 cm; BMI: 19.46.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-02041-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 200 mg.
- Sample C3L-02041-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 250 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-02041-22: Section location: Temporal Lobe; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-02041-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
